Somatic mutation profile of tumor specimen TCGA-EE-A2A1-06A (aliquot TCGA-EE-A2A1-06A-11D-A197-08) from TCGA case TCGA-EE-A2A1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.3 years (18,742 days).
Specimen TCGA-EE-A2A1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 323da25d-f767-466a-aeba-ea7f6a104c96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2A1-10A (Blood Derived Normal), aliquot TCGA-EE-A2A1-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e56fb33-2524-48fa-8f47-1608e1da5856

The open-access MAF lists 451 somatic variants for this specimen: 300 protein-altering or splice-affecting, 143 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 278, Silent 143, Nonsense Mutation 15, RNA 5, Frame Shift Ins 3, Intron 3, Splice Site 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NCR1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV52555848; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 23/147 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 19/184 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV61982533; called by muse, mutect2, varscan2
- ABCA4 | c.6299G>A p.G2100E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64678330; called by muse, mutect2
- ABCB1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV55955044; called by muse, mutect2, varscan2
- ABCC3 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV53320616; called by muse, mutect2, varscan2
- AC008397.2 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV53209857; called by muse, mutect2, varscan2
- AC132217.2 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs574503594, COSV56101798; called by muse, mutect2
- ACSL1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs770898537, COSV55666114, COSV55666648; called by mutect2, varscan2
- ACSS2 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 80/233 reads (34%) | catalogued as COSV53625787, COSV53628459; called by muse, mutect2, varscan2
- ACTRT2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs541837585, COSV65760607; called by muse, mutect2, varscan2
- ADAM10 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99545358; called by muse, mutect2, varscan2
- ADAM10 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99545361; called by muse, mutect2, varscan2
- ADAM2 | c.708A>T p.K236N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55868631; called by muse, mutect2, varscan2
- ADAM7 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs137990671, COSV51537987; called by muse, mutect2, varscan2
- ADD2 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as rs782815926, COSV52471804; called by muse, mutect2, varscan2
- AGAP1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs373781245; called by muse, mutect2, varscan2
- AKAP9 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV62358424; called by muse, mutect2
- AL441992.2 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1365483160, COSV100223314; called by muse, mutect2, varscan2
- ANG | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV59013256; called by muse, mutect2
- ANGPT1 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV52457555; called by muse, mutect2, varscan2
- ANK1 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV55896329; called by muse, mutect2, varscan2
- ANK3 | c.10338G>A p.W3446* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV55078735; called by muse, mutect2, varscan2
- ANK3 | c.5659C>T p.L1887F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV55082925; called by muse, mutect2, varscan2
- ANO2 | c.1129G>A p.G377R (on ENST00000356134 / NM_001278597.3; = p.G381R on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59020863, COSV59043946; called by muse, mutect2
- ANO5 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV61082319; called by muse, mutect2, varscan2
- AP002512.3 | c.1128G>A p.M376I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as COSV54408867; called by muse, mutect2, varscan2
- AP4E1 | c.3196C>T p.P1066S | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1369840406, COSV55918279; called by muse, mutect2
- ARMC10 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); catalogued as COSV58524129; called by muse, mutect2, varscan2
- ARMCX2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1556056896, COSV57531235; called by muse, mutect2, varscan2
- ARMCX6 | c.369T>G p.C123W | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as COSV62680976; called by muse, mutect2, varscan2
- ASH1L | c.3131C>G p.T1044S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64214050; called by muse, mutect2, varscan2
- ASH2L | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1563248967, COSV51701884; called by muse, mutect2, varscan2
- ATP2B2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as rs758872197, COSV59492313; called by muse, mutect2, varscan2
- B4GALNT2 | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55928376; called by muse, mutect2, varscan2
- BICC1 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65856649, COSV65865422; called by muse, mutect2
- BPTF | c.7505C>T p.P2502L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs782811761, COSV58847292; called by muse, mutect2, varscan2
- BSN | c.8572C>T p.P2858S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56528007; called by muse, mutect2, varscan2
- BZW2 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51757812; called by muse, mutect2
- C16orf78 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | catalogued as COSV54558526; called by muse, varscan2
- C1QTNF9 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.09); catalogued as COSV59658257; called by muse, mutect2
- C20orf194 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 160/395 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs1433673239, COSV52703246; called by muse, mutect2, varscan2
- C3AR1 | c.285C>G p.C95W | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50825120; called by muse, mutect2, varscan2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2, varscan2
- C4BPA | c.304T>C p.W102R | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65537708; called by muse, mutect2, varscan2
- CACNA1F | c.3231G>A p.M1077I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as rs782690400, COSV59907101; called by muse, mutect2, varscan2
- CACNA1I | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV60818895; called by muse, mutect2, varscan2
- CAMKK2 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1407341397, COSV61217904; called by muse, mutect2, varscan2
- CAP2 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57737276; called by muse, mutect2, varscan2
- CARD10 | c.2060-1G>A p.X687_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52660289; called by muse, mutect2, varscan2
- CARD11 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62716832; called by muse, mutect2, varscan2
- CARD9 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV53737933; called by muse, mutect2, varscan2
- CASP8AP2 | c.3962C>T p.S1321F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52750064; called by muse, mutect2, varscan2
- CCDC171 | c.2681C>T p.S894F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV52653125, COSV52653404; called by muse, mutect2
- CD276 | c.1151C>T p.S384F (on ENST00000318443 / NM_001024736.2; = p.S166F on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.926); catalogued as rs772688844, COSV59205772; called by muse, mutect2, varscan2
- CD74 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV50534660; called by muse, mutect2, varscan2
- CDH7 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.179); catalogued as COSV59895341; called by muse, mutect2
- CDX4 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.19); catalogued as COSV65171925; called by muse, mutect2
- CENPE | c.4043C>T p.T1348I | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV54394545; called by muse, mutect2
- CENPF | c.5549C>T p.S1850F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV65279230; called by muse, mutect2
- CEP164 | c.1991A>C p.E664A | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.78); catalogued as rs150261648; called by muse, mutect2, varscan2
- CEP95 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs782609312, COSV56751429; called by muse, mutect2
- CES1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62085963; called by muse, mutect2, varscan2
- CFAP299 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63871516; called by muse, mutect2, varscan2
- CFTR | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV50042068; called by muse, mutect2, varscan2
- CHGB | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | catalogued as COSV66761799; called by muse, mutect2, varscan2
- CHRNA6 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.219); catalogued as COSV52381094; called by muse, mutect2, varscan2
- CHRNA9 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs748025938, COSV59574500, COSV59576307; called by muse, mutect2, varscan2
- CIBAR2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.071); catalogued as rs267604672, COSV73320582; called by muse, mutect2, varscan2
- CLCA4 | c.2602C>T p.P868S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs769130665, COSV65285258; called by muse, mutect2, varscan2
- CNGA1 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs373782782; called by muse, mutect2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, mutect2, varscan2
- COL1A1 | c.3353G>A p.G1118D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56809657; called by muse, mutect2, varscan2
- COL21A1 | c.2327G>A p.G776E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55156829; called by muse, mutect2, varscan2
- COL21A1 | c.2326G>A p.G776R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1027851782, COSV99776951, COSV99779730; called by muse, mutect2, varscan2
- COL4A4 | c.3223G>A p.G1075S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100305920; called by muse, mutect2
- CPSF3 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53012028; called by muse, mutect2, varscan2
- CR1 | c.5584G>A p.G1862R | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs776158638, COSV100887627, COSV65463694; called by muse, mutect2
- CRY1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV50492205; called by muse, mutect2, varscan2
- CXCR1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV55281953, COSV55283046; called by muse, mutect2, varscan2
- CYP2B6 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57845374; called by mutect2, varscan2
- CYP4F3 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55413776; called by muse, mutect2, varscan2
- CYTH3 | c.928C>T p.P310S (on ENST00000396741; = p.P309S on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV60364620; called by muse, mutect2, varscan2
- DCAF4L2 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.368); catalogued as COSV60478296, COSV60482800; called by muse, mutect2, varscan2
- DDX3X | c.1336T>C p.F446L (on ENST00000399959; = p.F447L on NM_001356.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67864589; called by muse, mutect2, varscan2
- DGKK | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1557222798, COSV65707602; called by muse, mutect2, varscan2
- DMRT1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV66524989; called by muse, mutect2, varscan2
- DNAH5 | c.1822A>G p.T608A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV54253207; called by muse, mutect2
- DNM3 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV62467672; called by muse, mutect2, varscan2
- EPC2 | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as rs1463279431, COSV51547529; called by muse, mutect2
- EPGN | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59741051; called by muse, mutect2, varscan2
- EPHA8 | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV51292490; called by muse, mutect2, varscan2
- ERICH3 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs764901117, COSV58607213; called by muse, mutect2, varscan2
- ERICH3 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs766243088, COSV58617523; called by muse, mutect2, varscan2
- ETV5 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV60506935; called by muse, mutect2, varscan2
- EVPL | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV56916373; called by muse, mutect2, varscan2
- FAM13A | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765968303, COSV52013528; called by muse, mutect2, varscan2
- FAM184A | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58858949; called by muse, mutect2, varscan2
- FAM71B | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 114/661 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57231386; called by muse, mutect2, varscan2
- FCRL4 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.364); catalogued as COSV54866652; called by muse, mutect2, varscan2
- FCSK | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55374840; called by muse, mutect2, varscan2
- FGFBP1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52587320; called by muse, mutect2, varscan2
- FLNB | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV55896233; called by muse, mutect2, varscan2
- FNDC3A | c.2180C>T p.P727L (on ENST00000492622 / NM_001079673.2; = p.P671L on NM_014923.5) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV68135168; called by muse, mutect2, varscan2
- FRAS1 | c.8974G>A p.V2992I | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV53649789; called by muse, mutect2
- FREM2 | c.6871C>T p.H2291Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.661); catalogued as COSV54853078; called by muse, mutect2, varscan2
- FXYD7 | c.61+1G>A p.X21_splice | Splice Site (SNP) | VAF 16/127 reads (13%) | catalogued as COSV54344178; called by muse, mutect2, varscan2
- FYB1 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs866853713, COSV60948018; called by muse, mutect2
- GABRP | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs558177227, COSV54661976; called by muse, mutect2, varscan2
- GNA14 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236188811, COSV59029751; called by muse, mutect2, varscan2
- GRAMD1B | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1207068677, COSV100454805, COSV59203800; called by muse, mutect2, varscan2
- GRIN3A | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs145326290, COSV62450102; called by muse, varscan2
- HAVCR2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 91/733 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57154867; called by muse, mutect2, varscan2
- HCN4 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV56087596; called by muse, mutect2, varscan2
- HECTD4 | c.7927G>A p.G2643S | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66400142; called by muse, mutect2, varscan2
- HEPH | c.3410G>A p.R1137K (on ENST00000343002; = p.R870K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs1468153622, COSV57972657; called by muse, mutect2, varscan2
- HERC2 | c.7907C>T p.S2636F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV55351064; called by muse, mutect2, varscan2
- HSPH1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.017); catalogued as COSV60714029; called by muse, mutect2, varscan2
- HTR3D | c.1327T>C p.S443P (on ENST00000382489 / NM_001163646.2; = p.S268P on NM_182537.3) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV61915649; called by muse, mutect2
- IGFBPL1 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV66618647; called by muse, mutect2, varscan2
- IGHV3-23 | c.136T>A p.F46I | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs782809838; called by muse, mutect2
- IGHV3-23 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); catalogued as rs782126785; called by muse, mutect2
- IGSF9 | c.3265G>A p.D1089N (on ENST00000368094 / NM_001135050.2; = p.D1073N on NM_020789.4) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57423723; called by muse, mutect2, varscan2
- IKZF3 | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV53102084; called by muse, mutect2
- IL37 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1308467350, COSV54493165; called by muse, mutect2, varscan2
- INHBA | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs765780968, COSV54220741; called by muse, mutect2, varscan2
- IRF6 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.957); catalogued as COSV65420446; called by muse, mutect2, varscan2
- ITGB3 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV71385258; called by muse, mutect2, varscan2
- ITPR2 | c.5812-1G>A p.X1938_splice | Splice Site (SNP) | VAF 15/92 reads (16%) | catalogued as COSV67276404; called by muse, mutect2
- KCNH1 | c.1591G>A p.G531R (on ENST00000271751 / NM_172362.3; = p.G504R on NM_002238.4) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV55099428, COSV55105260; called by muse, varscan2
- KCNK5 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.024); catalogued as COSV63989452; called by mutect2, varscan2
- KCNV2 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.132); catalogued as rs770351405, COSV66055604; called by muse, mutect2, varscan2
- KIAA0232 | c.3097C>T p.P1033S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV56929598; called by muse, mutect2, varscan2
- KIAA1210 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.361); catalogued as COSV68180351; called by muse, mutect2, varscan2
- KRT6C | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV52880642; called by muse, mutect2, varscan2
- KRT78 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV58853860; called by muse, mutect2, varscan2
- KRT78 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs375440936; called by muse, mutect2, varscan2
- LARP4 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.245); catalogued as rs370676327, COSV53328230; called by muse, mutect2, varscan2
- LIPI | c.793T>C p.S265P | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV60711783; called by muse, mutect2, varscan2
- LPAR4 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70913481; called by muse, mutect2
- LRIG1 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56248428; called by muse, mutect2, varscan2
- LRP2 | c.13259C>T p.P4420L | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV55575429; called by muse, mutect2, varscan2
- LTBP3 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as rs1400831758, COSV57238921; called by muse, mutect2, varscan2
- LUC7L2 | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54929273; called by muse, mutect2, varscan2
- MAGEB1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781441089, COSV66776670; called by muse, mutect2
- MAGEB16 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV67874658; called by muse, mutect2
- MAN2A2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 93/325 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs753230592, COSV64638746; called by muse, mutect2, varscan2
- MAP10 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs1343507214, COSV69365037; called by muse, mutect2, varscan2
- MARCHF10 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as COSV60890553; called by muse, mutect2, varscan2
- MARCO | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV59058904; called by muse, mutect2, varscan2
- MECOM | c.862C>T p.P288S (on ENST00000468789 / NM_001105078.4; = p.P476S on NM_004991.4) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1406835103, COSV52975261; called by muse, mutect2, varscan2
- MIGA1 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as COSV66225066; called by muse, mutect2
- MOGS | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99270197; called by muse, varscan2
- MOGS | c.936T>G p.S312R | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV99270198; called by muse, varscan2
- MROH2B | c.4429G>A p.D1477N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as COSV68180970; called by muse, varscan2
- MROH5 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV71302944; called by muse, mutect2, varscan2
- MUC16 | c.23995C>T p.L7999F | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1160215047, COSV67476177; called by muse, mutect2
- MUC16 | c.8557A>G p.T2853A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67495344; called by muse, mutect2
- MYCBP2 | c.530G>A p.R177Q (on ENST00000357337; = p.R215Q on NM_015057.5) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as rs1220717411, COSV62039886; called by muse, mutect2, varscan2
- MYLK | c.531G>A p.M177I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV60623098; called by muse, mutect2
- NALCN | c.4654G>A p.E1552K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51945688; called by muse, mutect2, varscan2
- NAPSA | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53799194; called by muse, mutect2, varscan2
- NCK2 | c.855G>T p.W285C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51896579; called by muse, mutect2, varscan2
- NCKAP1L | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53212561; called by muse, mutect2, varscan2
- NKD1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV51693537; called by muse, mutect2, varscan2
- NLRP12 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as COSV60755569; called by muse, mutect2, varscan2
- NOL4 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); catalogued as rs945553282, COSV52347422, COSV52350395; called by muse, mutect2, varscan2
- NONO | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52136998, COSV52138484; called by muse, mutect2, varscan2
- NPR2 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61313426; called by muse, mutect2, varscan2
- NRAP | c.4013G>A p.G1338D (on ENST00000359988 / NM_001322945.2; = p.G1303D on NM_006175.4) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV63494138; called by muse, mutect2, varscan2
- NRK | c.3121G>A p.G1041R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.18); catalogued as COSV54607237; called by muse, mutect2, varscan2
- NRP1 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55177837, COSV99589408; called by muse, mutect2, varscan2
- NRXN3 | c.2030G>A p.R677K (on ENST00000335750 / NM_001330195.2; = p.R304K on NM_004796.6) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.958); catalogued as COSV59810246; called by muse, mutect2, varscan2
- NUAK1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs748065457, COSV54602934; called by mutect2, varscan2
- NUDT7 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV51747242; called by muse, mutect2, varscan2
- NUP210L | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1304865611, COSV55141324; called by muse, mutect2, varscan2
- NUTM2G | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369517591; called by muse, mutect2, varscan2
- OR10H1 | c.794G>A p.S265N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs758116187, COSV58473141; called by muse, mutect2, varscan2
- OR11H12 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 14/225 reads (6%) | catalogued as COSV101612449; called by muse, mutect2
- OR1C1 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.533); catalogued as COSV68716413; called by muse, mutect2
- OR2W1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1226192074, COSV65851432, COSV65851562, COSV65852021; called by muse, mutect2, varscan2
- OR51B6 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66513981; called by muse, mutect2, varscan2
- OR51L1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs1239718091, COSV58624107; called by muse, mutect2, varscan2
- OR52E6 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1467967813, COSV61433541; called by muse, mutect2, varscan2
- OR6K2 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs754506493, COSV62743313, COSV62743319; called by muse, mutect2, varscan2
- OSBPL6 | c.2335C>T p.Q779* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV51930997; called by muse, mutect2, varscan2
- PABPC4 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV63293708; called by muse, mutect2, varscan2
- PABPN1L | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV56352866; called by muse, mutect2, varscan2
- PARN | c.1451C>A p.S484Y | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58364662, COSV58371282; called by muse, mutect2, varscan2
- PBX1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV63346078; called by muse, mutect2, varscan2
- PCDH15 | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.955); catalogued as COSV64695014; called by muse, mutect2
- PCDH18 | c.2848C>T p.P950S | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61272311; called by muse, mutect2, varscan2
- PCDHA1 | c.2018G>A p.G673D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV65374321; called by muse, mutect2, varscan2
- PCDHAC1 | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV53859438; called by muse, mutect2, varscan2
- PCDHB4 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.309); catalogued as COSV52026173; called by muse, mutect2, varscan2
- PCDHGA4 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs778228688, COSV54037420; called by muse, mutect2, varscan2
- PCLO | c.12397C>T p.R4133C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372497499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDZD2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as rs777626634, COSV56859928; called by muse, mutect2, varscan2
- PDZD2 | c.194A>C p.E65A | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs748890876, COSV56862936, COSV99223216; called by muse, mutect2, varscan2
- PHF24 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1200428587, COSV54277084; called by muse, mutect2, varscan2
- PIGB | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179198642, COSV51241309; called by muse, mutect2
- PKD1 | c.5401C>T p.P1801S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs766934384, COSV51926010; called by muse, mutect2
- PKHD1L1 | c.8713C>T p.H2905Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV65753681; called by muse, mutect2
- PKN3 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as COSV52579868; called by muse, mutect2, varscan2
- PLA2G4A | c.1636C>T p.H546Y | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.999); catalogued as COSV66551948, COSV66557100; called by muse, mutect2
- PLA2G7 | c.980A>C p.N327T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as COSV51266211; called by muse, mutect2, varscan2
- PLCB4 | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53794447; called by muse, mutect2
- PLCH1 | c.158G>A p.W53* (on ENST00000340059 / NM_001130960.2; = p.W65* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/163 reads (18%) | catalogued as COSV58210534; called by muse, mutect2, varscan2
- PLD5 | c.1402G>A p.G468S (on ENST00000442594; = p.G406S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59168859; called by muse, mutect2, varscan2
- PNLIPRP3 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293183373, COSV65049741; called by muse, mutect2, varscan2
- PPFIA2 | c.2879A>G p.E960G | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61055845; called by muse, mutect2
- PRB3 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 44/376 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.113); catalogued as COSV54393608; called by muse, varscan2
- PRB4 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs865985353, COSV54397886; called by muse, mutect2, varscan2
- PRKCA | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV52592423, COSV52596117; called by muse, mutect2, varscan2
- PRKCB | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs754563290, COSV57802443; called by muse, mutect2, varscan2
- PRSS23 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.197); catalogued as COSV54707704; called by muse, mutect2, varscan2
- PRSS58 | c.707A>T p.N236I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV73488869; called by muse, mutect2, varscan2
- PRUNE2 | c.4141G>C p.G1381R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV65048247; called by muse, mutect2, varscan2
- PTPRH | c.2341A>C p.K781Q | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV54750337; called by muse, mutect2, varscan2
- PTPRZ1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV66445947; called by muse, mutect2, varscan2
- PXDNL | c.4117C>T p.Q1373* | Nonsense Mutation (SNP) | VAF 10/114 reads (9%) | catalogued as COSV62483748; called by muse, mutect2
- QARS1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766000850, COSV60274083; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753891803, COSV54764297; called by muse, mutect2, varscan2
- RBM25 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56203949; called by muse, mutect2, varscan2
- RELN | c.1376G>A p.R459K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV59034522; called by muse, mutect2, varscan2
- REST | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs1259814228, COSV58363078; called by muse, mutect2, varscan2
- RGS18 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs988087391, COSV100817909, COSV66507541; called by muse, mutect2, varscan2
- RGS7BP | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61833475, COSV61835070; called by muse, mutect2, varscan2
- RHBDD2 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV50089235; called by muse, mutect2, varscan2
- RHBDF1 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.497); catalogued as rs774630076, COSV51958229; called by muse, mutect2, varscan2
- RHOXF1 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99483669; called by muse, mutect2, varscan2
- ROBO2 | c.2110A>C p.K704Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV59940110; called by muse, varscan2
- RUNX1T1 | c.175C>T p.P59S (on ENST00000265814 / NM_001198628.1; = p.P32S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.652); catalogued as COSV56137375, COSV56150880; called by muse, mutect2
- SCN5A | c.3947G>A p.R1316Q (on ENST00000333535 / NM_198056.3; = p.R1315Q on NM_000335.5) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs765907469, CM143810, COSV100346967, COSV61139531; called by muse, mutect2
- SCYL3 | c.1873C>T p.L625F (on ENST00000367770; = p.L571F on NM_020423.7) | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs376335762; called by muse, mutect2, varscan2
- SERPINA7 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | catalogued as COSV59666289, COSV59667198; called by muse, mutect2, varscan2
- SHH | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV51920393; called by muse, mutect2, varscan2
- SKAP2 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61728089; called by muse, mutect2, varscan2
- SLAIN1 | c.1661C>T p.S554L (on ENST00000466548; = p.S291L on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV57389422; called by muse, mutect2, varscan2
- SLC16A1 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63710401; called by muse, mutect2
- SLC6A11 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767646133, COSV54399135; called by muse, mutect2, varscan2
- SLC8A1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370199920, COSV60480168, COSV60495926; called by muse, mutect2, varscan2
- SLC8A1 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | catalogued as COSV60475860, COSV60494347, COSV60497125; called by muse, mutect2, varscan2
- SLC8A3 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV100775805; called by muse, mutect2, varscan2
- SNCAIP | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs267600329, COSV54401647; called by muse, mutect2, varscan2
- SORD | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51045226; called by muse, mutect2, varscan2
- SPON1 | c.1591T>G p.F531V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.264); catalogued as COSV59968582; called by muse, mutect2, varscan2
- SRCAP | c.3833C>T p.S1278L | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.758); catalogued as rs755307689, COSV52675880; called by muse, mutect2, varscan2
- STK11IP | c.230T>C p.F77S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV55255844; called by muse, mutect2, varscan2
- STK31 | c.2657A>G p.N886S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV63459598; called by muse, mutect2, varscan2
- STT3A | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV67065530; called by muse, mutect2, varscan2
- STXBP4 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54843953; called by muse, mutect2, varscan2
- SUGP1 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs751111684, COSV55924173; called by muse, mutect2, varscan2
- SUGP2 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV58257785; called by muse, mutect2, varscan2
- SULF1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV52686432, COSV99481718; called by muse, mutect2, varscan2
- SYBU | c.143C>T p.P48L (on ENST00000276646 / NM_001099754.2; = p.P47L on NM_017786.6) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV52623270; called by muse, mutect2, varscan2
- TARS2 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV64696979; called by muse, mutect2
- TCOF1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV60354610; called by muse, mutect2, varscan2
- THSD7B | c.3538G>A p.E1180K (on ENST00000272643; = p.E1178K on NM_001316349.2) | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.699); catalogued as COSV55655747, COSV99742785; called by muse, mutect2, varscan2
- TIMD4 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 62/547 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV50855418; called by muse, mutect2, varscan2
- TIMELESS | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as COSV57515396; called by muse, mutect2, varscan2
- TLN2 | c.6775C>T p.L2259F | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV60896045; called by muse, mutect2, varscan2
- TMEM132A | c.1376C>T p.A459V (on ENST00000453848 / NM_178031.3; = p.A460V on NM_017870.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV50017010; called by muse, mutect2, varscan2
- TNFRSF21 | c.1460G>A p.R487K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57283736, COSV57285251; called by mutect2, varscan2
- TRIM24 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV58975305; called by muse, mutect2
- TRPC5 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53284912; called by muse, mutect2, varscan2
- TRPM6 | c.5837G>A p.G1946E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.666); catalogued as COSV62523068; called by muse, mutect2, varscan2
- TSHB | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1185914926, COSV56655629, COSV56656155; called by muse, mutect2, varscan2
- TUBA3C | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV68028257; called by muse, mutect2, varscan2
- TUBA3D | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); catalogued as COSV100343000, COSV58313359; called by muse, mutect2, varscan2
- TXK | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.791); catalogued as rs757604544, COSV51915536; called by muse, mutect2, varscan2
- UBL7 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.787); catalogued as COSV63706780; called by muse, mutect2, varscan2
- UBR2 | c.3851C>T p.P1284L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV65752677; called by muse, mutect2, varscan2
- UNC13C | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV52858169; called by muse, mutect2
- UPF3A | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV60896202; called by muse, mutect2
- USH2A | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs368754739; called by muse, mutect2, varscan2
- USP25 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 28/159 reads (18%) | catalogued as COSV53490664; called by muse, mutect2, varscan2
- USP26 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV63709873; called by muse, mutect2, varscan2
- VN1R2 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV59039728, COSV59039765; called by muse, mutect2, varscan2
- VWF | c.8059G>A p.E2687K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54635137; called by muse, mutect2, varscan2
- WDR17 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54584430; called by muse, mutect2
- ZC3H12C | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV53713025; called by muse, mutect2, varscan2
- ZDHHC6 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65565351; called by muse, mutect2, varscan2
- ZNF142 | c.3382C>T p.P1128S (on ENST00000411696 / NM_001379660.1; = p.P928S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV101376886; called by muse, mutect2, varscan2
- ZNF317 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV56111664; called by muse, mutect2, varscan2
- ZNF479 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1435808529, COSV58640914; called by muse, mutect2
- ZNF48 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs755489550, COSV60784384; called by muse, varscan2
- ZNF512 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62678426; called by muse, mutect2, varscan2
- ZNF521 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV64132103; called by muse, mutect2, varscan2
- ZNF586 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101656721; called by muse, mutect2, varscan2
- ZNF813 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1285563398, COSV67176200; called by muse, mutect2, varscan2
- ZSCAN2 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57572026; called by muse, mutect2, varscan2
- ACACA | c.1174dup p.S392Ffs*23 | Frame Shift Ins (INS) | VAF 14/115 reads (12%) | called by mutect2, pindel, varscan2
- ASH1L | c.8803dup p.I2935Nfs*8 (on ENST00000368346 / NM_001366177.2; = p.I2930Nfs*8 on NM_018489.3) | Frame Shift Ins (INS) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- EPHX2 | c.1076del p.N359Ifs*43 | Frame Shift Del (DEL) | VAF 17/152 reads (11%) | called by mutect2, pindel, varscan2
- FOS | c.884_885dup p.G296Lfs*116 | Frame Shift Ins (INS) | VAF 10/83 reads (12%) | called by mutect2, pindel, varscan2
- IGHV3-38 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- TBCK | c.1524T>G p.D508E (on ENST00000273980 / NM_001163436.4; = p.D445E on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAV7 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ZP1 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.432); called by muse, mutect2
- ABCC8 | c.2250C>T p.D750= | Silent (SNP) | VAF 57/385 reads (15%) | catalogued as COSV56858059; called by muse, mutect2, varscan2
- AC126283.2 | c.696G>A p.G232= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs144145014, COSV67099694; called by muse, mutect2, varscan2
- ACIN1 | c.1233G>A p.E411= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV52982448; called by muse, mutect2, varscan2
- ACSF2 | c.276C>T p.V92= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs767231964, COSV51974281; called by muse, mutect2
- ACSM1 | c.1353G>A p.G451= | Silent (SNP) | VAF 126/515 reads (24%) | catalogued as COSV54640306; called by muse, mutect2, varscan2
- ADAM7 | c.954C>T p.I318= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV51545823, COSV99442708; called by muse, mutect2
- ADAMTS13 | c.1476G>A p.E492= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV63023229; called by muse, mutect2, varscan2
- ADAMTS15 | c.2094C>T p.F698= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs267602783, COSV54503735; called by mutect2, varscan2
- ADAMTS6 | c.2394C>T p.S798= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV66864993; called by muse, mutect2, varscan2
- ADNP2 | c.2457C>T p.L819= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs946452150, COSV51542556; called by muse, mutect2, varscan2
- AHSP | c.243C>T p.F81= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV56528649; called by muse, mutect2, varscan2
- ANK3 | c.3567G>A p.V1189= (on ENST00000280772 / NM_001320874.2; = p.V323= on NM_001149.3) | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV55082934; called by muse, mutect2
- ANXA2 | c.351C>T p.S117= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV60318837, COSV60319371; called by muse, mutect2, varscan2
- ARHGEF10 | c.2829C>T p.S943= (on ENST00000398564; = p.S918= on NM_014629.4) | Silent (SNP) | VAF 19/172 reads (11%) | catalogued as COSV50679724; called by muse, mutect2, varscan2
- ATG2B | c.5907C>T p.I1969= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs267604117, COSV55890451; called by muse, mutect2, varscan2
- C10orf120 | c.510G>A p.R170= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV61492679; called by muse, mutect2, varscan2
- C16orf78 | c.48G>A p.R16= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV54556205; called by muse, varscan2
- C1orf87 | c.1459C>T p.L487= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs764263654, COSV64597142; called by mutect2, varscan2
- C1orf87 | c.1458C>T p.Y486= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100966871; called by mutect2, varscan2
- C5AR1 | c.954C>T p.L318= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs754477439, COSV61892242; called by muse, mutect2, varscan2
- C6 | c.1794G>A p.G598= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as COSV54707422; called by muse, mutect2, varscan2
- C8A | c.1473G>A p.L491= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs1557716942, COSV63486568; called by muse, mutect2, varscan2
- CACNA1G | c.1173G>A p.L391= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV61739964; called by muse, mutect2, varscan2
- CAVIN2 | c.939C>T p.T313= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as COSV58425836; called by muse, mutect2, varscan2
- CD207 | c.972C>T p.V324= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV69652787; called by muse, mutect2, varscan2
- CD300A | c.234G>A p.R78= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV60410769, COSV60411126; called by muse, mutect2, varscan2
- CDH13 | c.1110C>T p.A370= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs367637876; called by muse, mutect2, varscan2
- CDH20 | c.291C>T p.I97= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1172090392, COSV53005133, COSV99403947; called by muse, mutect2, varscan2
- CENPE | c.4044C>T p.T1348= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99476708; called by muse, mutect2
- CEP164 | c.1992G>A p.E664= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs1455115278, COSV99632336; called by muse, mutect2, varscan2
- CFAP54 | c.5037C>T p.F1679= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV61575403; called by muse, mutect2, varscan2
- CLDN4 | c.429C>T p.I143= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV52897254; called by muse, mutect2, varscan2
- CMYA5 | c.2049G>A p.E683= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV71409621; called by muse, mutect2, varscan2
- COL18A1 | c.2683C>T p.L895= (on ENST00000359759 / NM_130444.3; = p.L660= on NM_030582.4) | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV62707495; called by muse, mutect2, varscan2
- COL1A1 | c.783C>T p.L261= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs369971149; called by muse, mutect2, varscan2
- COL7A1 | c.4044G>A p.E1348= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV60403409; called by muse, mutect2, varscan2
- COPG1 | c.1849T>C p.L617= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV59116602; called by muse, mutect2, varscan2
- CSMD1 | c.8511T>A p.S2837= (on ENST00000520002; = p.S2836= on NM_033225.6) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100141872; called by muse, mutect2
- CSMD2 | c.7569C>T p.I2523= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99584408, COSV99594407; called by muse, mutect2, varscan2
- CTC1 | c.1332C>T p.S444= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV59855595; called by muse, mutect2, varscan2
- CTNNA2 | c.30G>A p.L10= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100784772, COSV63602666, COSV63603564; called by muse, mutect2, varscan2
- CYP4A11 | c.915C>T p.I305= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV60224330; called by muse, mutect2, varscan2
- CYP4F11 | c.858C>T p.F286= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV56126107; called by muse, mutect2
- CYP4Z1 | c.162C>T p.F54= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV61966767, COSV61966816; called by muse, mutect2
- DDR2 | c.1338C>T p.S446= | Silent (SNP) | VAF 25/213 reads (12%) | catalogued as COSV63370164; called by muse, mutect2, varscan2
- DENND11 | c.393C>T p.F131= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs757787992, COSV72097819; called by muse, mutect2, varscan2
- DHPS | c.498C>T p.I166= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs780863009, COSV52953382; called by muse, mutect2, varscan2
- DNAH3 | c.11298C>T p.L3766= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs536339888, COSV54553182; called by muse, mutect2, varscan2
- DNAH5 | c.7950G>A p.K2650= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV54205435; called by muse, mutect2, varscan2
- DSCAM | c.1092G>A p.G364= | Silent (SNP) | VAF 64/319 reads (20%) | catalogued as rs771176555, COSV68021788; called by muse, mutect2, varscan2
- DYNC2H1 | c.1830C>T p.F610= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV62107252; called by muse, mutect2, varscan2
- FAM47C | c.2760G>A p.G920= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV63725982; called by muse, mutect2, varscan2
- FAT3 | c.1845C>T p.I615= | Silent (SNP) | VAF 64/503 reads (13%) | catalogued as COSV53082934; called by muse, mutect2, varscan2
- FBXO16 | c.519G>A p.K173= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV60776108; called by muse, mutect2, varscan2
- FBXO24 | c.1725C>T p.P575= (on ENST00000241071 / NM_033506.3; = p.P613= on NM_012172.5) | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV53823331; called by muse, mutect2
- FCRL6 | c.1275C>T p.P425= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV58942762; called by muse, mutect2, varscan2
- GABRB1 | c.961C>T p.L321= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV54984916, COSV55000387; called by muse, mutect2
- GP5 | c.771C>T p.L257= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs1035218886, COSV59880271; called by muse, mutect2, varscan2
- GPR35 | c.486C>T p.C162= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV60578713; called by muse, mutect2, varscan2
- GPR87 | c.567C>T p.I189= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV53464596; called by muse, mutect2, varscan2
- HOXB7 | c.582G>A p.K194= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as rs905774240, COSV53311630; called by muse, mutect2, varscan2
- HS2ST1 | c.81G>A p.L27= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV59357339; called by muse, mutect2, varscan2
- IFNA21 | c.489C>T p.A163= | Silent (SNP) | VAF 46/287 reads (16%) | catalogued as rs1053887, COSV66519022; called by muse, mutect2, varscan2
- IGFN1 | c.3339G>A p.R1113= (on ENST00000295591 / NM_001367841.1; = p.R3570= on NM_001164586.2) | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs547293166, COSV55173740, COSV55175487; called by muse, mutect2, varscan2
- IL24 | c.351G>A p.L117= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV54321774; called by muse, mutect2, varscan2
- INHA | c.88C>T p.L30= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1156448678, COSV54730076; called by muse, mutect2, varscan2
- IQCH | c.1335G>A p.R445= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs750156139, COSV60060195; called by muse, mutect2, varscan2
- KCNK10 | c.1470G>A p.T490= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs113347660; called by muse, mutect2, varscan2
- KIF4B | c.1806C>T p.L602= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV70531644; called by muse, mutect2, varscan2
- LILRA2 | c.642G>A p.E214= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as COSV52197075; called by muse, mutect2
- LIN54 | c.2199C>T p.V733= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV61202922; called by muse, mutect2, varscan2
- LMX1A | c.294C>T p.F98= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs770228573, COSV54215934; called by muse, varscan2
- LRP1B | c.7770C>T p.T2590= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs763179654, COSV67276649; called by muse, mutect2
- LRP1B | c.1521C>T p.F507= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV67206779, COSV67276651; called by muse, mutect2, varscan2
- LRRC8E | c.1431C>T p.S477= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV60719317; called by muse, mutect2
- MAN2B2 | c.484C>T p.L162= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV53457080; called by muse, mutect2, varscan2
- MAP2 | c.756C>T p.L252= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV52308659; called by muse, mutect2
- MICALL2 | c.1881C>T p.S627= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs200214323; called by muse, mutect2, varscan2
- MS4A15 | c.594C>T p.I198= (on ENST00000405633 / NM_001098835.2; = p.I105= on NM_152717.3) | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV61961884; called by muse, mutect2, varscan2
- MTUS2 | c.1008G>A p.K336= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV70922991; called by muse, mutect2, varscan2
- MYH13 | c.4077C>T p.A1359= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as rs1453309267, COSV52823995, COSV52838086; called by muse, mutect2, varscan2
- NEUROG1 | c.483G>A p.R161= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- NMNAT2 | c.345C>T p.S115= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV54269281, COSV54272084; called by muse, mutect2, varscan2
- NOX4 | c.610C>T p.L204= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV104372973, COSV54465226; called by muse, mutect2, varscan2
- NSD2 | c.1128C>T p.S376= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV56396785; called by muse, mutect2, varscan2
- NUP210L | c.3363G>A p.Q1121= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV55158219; called by muse, mutect2, varscan2
- OR2A25 | c.33C>T p.F11= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as rs367951090; called by muse, mutect2, varscan2
- OR4X1 | c.261G>A p.R87= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs977095941, COSV60722409; called by muse, mutect2, varscan2
- OR52K1 | c.843C>T p.F281= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as COSV100297736, COSV56904811; called by muse, mutect2, varscan2
- OR52M1 | c.489G>A p.L163= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV64172867; called by muse, mutect2, varscan2
- OR6C1 | c.132C>T p.I44= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1426393595, COSV65573634, COSV65574530; called by muse, mutect2, varscan2
- OR8S1 | c.42C>T p.L14= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as COSV59600907; called by muse, mutect2, varscan2
- PADI3 | c.1287C>T p.L429= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV64935193; called by muse, mutect2, varscan2
- PCLO | c.12282C>T p.F4094= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs757947018, COSV61665886; called by muse, mutect2, varscan2
- PCSK2 | c.1047C>T p.S349= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV52743748; called by muse, mutect2
- PDE6C | c.582C>T p.I194= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as COSV65117821; called by muse, mutect2, varscan2
- PLEKHG1 | c.721C>T p.L241= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV62048747; called by muse, mutect2, varscan2
- PROKR2 | c.813G>A p.R271= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV54089392; called by muse, mutect2
- PRPF31 | c.639C>T p.S213= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1276572328, COSV58086322, COSV58087341; called by muse, mutect2, varscan2
- PSAT1 | c.543C>T p.F181= | Silent (SNP) | VAF 52/371 reads (14%) | catalogued as rs1254688718, COSV61303092; called by muse, mutect2, varscan2
- PTK7 | c.732C>T p.F244= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV57851602; called by muse, mutect2
- PZP | c.1347C>T p.S449= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV54370615; called by muse, mutect2, varscan2
- RAB40AL | c.678C>T p.S226= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV54435869; called by muse, mutect2, varscan2
- RBM25 | c.423C>T p.L141= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs767985856, COSV56201061; called by muse, mutect2, varscan2
- RBP3 | c.3717G>A p.R1239= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- RGS21 | c.363G>A p.K121= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs1408992138, COSV101313979, COSV69883991; called by muse, mutect2, varscan2
- RGS7 | c.120A>G p.G40= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV58561630; called by muse, mutect2, varscan2
- RMC1 | c.1332C>T p.L444= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV52574812; called by muse, mutect2, varscan2
- RNF17 | c.2079C>T p.F693= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- SAMD3 | c.1542A>G p.G514= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV62389044; called by muse, mutect2, varscan2
- SBSN | c.1617G>A p.K539= (on ENST00000452271 / NM_001166034.2; = p.K196= on NM_198538.4) | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as COSV71733361; called by muse, mutect2, varscan2
- SCN3A | c.4981C>T p.L1661= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV51825023; called by muse, mutect2, varscan2
- SCN5A | c.1071C>T p.S357= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV61139474, COSV61141317; called by muse, mutect2, varscan2
- SEMA3G | c.1608G>A p.R536= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1559609230, COSV51598613; called by muse, mutect2, varscan2
- SLC39A8 | c.1170C>T p.F390= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs143526887; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC44A5 | c.1359C>T p.I453= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV63775153; called by muse, mutect2, varscan2
- SLCO1A2 | c.996C>T p.F332= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs111579988, COSV56599368; called by mutect2, varscan2
- SLIT3 | c.2049C>T p.I683= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs745360694, COSV60633968; called by muse, mutect2, varscan2
- SNX13 | c.2127C>T p.S709= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV68068258; called by muse, mutect2, varscan2
- SORL1 | c.1515C>T p.I505= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as rs545101541, COSV52750066; called by muse, mutect2, varscan2
- SPDEF | c.405G>A p.E135= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV65001511, COSV65001775; called by muse, mutect2, varscan2
- SPHKAP | c.609G>A p.T203= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs1246576109, COSV60869524; called by muse, mutect2, varscan2
- STAG3 | c.2775C>T p.S925= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV57935171; called by muse, mutect2, varscan2
- SULF1 | c.987G>A p.G329= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV52682379; called by muse, mutect2, varscan2
- TAF2 | c.3588C>T p.S1196= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV65417677; called by muse, mutect2, varscan2
- TBC1D9 | c.3375C>T p.S1125= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs768257529, COSV71309055; called by muse, mutect2, varscan2
- TECTA | c.798C>T p.F266= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV50703030, COSV50721064; called by muse, mutect2, varscan2
- THSD7B | c.1518G>A p.G506= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV55649299; called by muse, mutect2, varscan2
- TMEM255B | c.942C>T p.Y314= | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as COSV64714983; called by muse, mutect2, varscan2
- TRAV26-1 | c.192C>T p.I64= | Silent (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- TRHDE | c.2613C>T p.F871= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs868074174, COSV53832593, COSV53835459; called by muse, mutect2, varscan2
- TSGA10 | c.2094C>T p.F698= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1466369900, COSV61825843; called by muse, mutect2, varscan2
- TSHZ2 | c.108C>T p.S36= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs752591081, COSV61591078; called by muse, mutect2, varscan2
- TSKS | c.1470C>T p.S490= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV55879493; called by muse, mutect2, varscan2
- TSKS | c.555G>A p.L185= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs755430915, COSV55873750, COSV55879509; called by muse, mutect2, varscan2
- TTN | c.77529T>C p.D25843= (on ENST00000591111; = p.D18419= on NM_003319.4) | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as COSV60360349; called by muse, mutect2
- TTN | c.1818G>A p.R606= (on ENST00000591111; = p.R560= on NM_003319.4) | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV60001972; called by muse, mutect2, varscan2
- ZNF142 | c.3708C>T p.S1236= (on ENST00000411696 / NM_001379660.1; = p.S1036= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV68745823; called by muse, mutect2, varscan2
- ZNF142 | c.3381A>T p.P1127= (on ENST00000411696 / NM_001379660.1; = p.P927= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 25/228 reads (11%) | catalogued as COSV101376887; called by muse, mutect2
- ZNF300 | c.94C>T p.L32= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV51050779; called by muse, mutect2, varscan2
- ZNF568 | c.1869C>T p.F623= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV61742949, COSV61743107; called by muse, mutect2, varscan2
- ZNF813 | c.588C>T p.F196= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV67176556; called by muse, mutect2, varscan2
- ZSCAN20 | c.720C>T p.L240= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV63684600; called by muse, mutect2, varscan2
- AGAP7P | n.1682G>A | RNA (SNP) | VAF 20/182 reads (11%) | catalogued as rs267602515; called by muse, mutect2, varscan2
- DCHS2 | n.3589G>A | RNA (SNP) | VAF 23/129 reads (18%) | catalogued as COSV59721835; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85947G>A | Intron (SNP) | VAF 24/150 reads (16%) | catalogued as rs1180182454, COSV72282969; called by muse, mutect2, varscan2
- PRRX1 | c.599+3893G>A | Intron (SNP) | VAF 110/313 reads (35%) | catalogued as COSV53413993, COSV99509081; called by muse, mutect2, varscan2
- SNORD115-26 | n.1G>T | RNA (SNP) | VAF 31/263 reads (12%) | catalogued as rs776874070; called by muse, mutect2, varscan2
- SNORD115-3 | n.68A>C | RNA (SNP) | VAF 26/340 reads (8%) | catalogued as rs1399082825; called by muse, mutect2
- SNORD116-25 | n.88G>A | RNA (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.10361-5366G>A | Intron (SNP) | VAF 9/65 reads (14%) | catalogued as rs1337811066, COSV100589265; called by muse, mutect2, varscan2
